Somatic mutation profile of tumor specimen TCGA-27-1837-01A (aliquot TCGA-27-1837-01A-01W-0837-08) from TCGA case TCGA-27-1837, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 36.6 years (13,368 days).
Specimen TCGA-27-1837-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 533c0618-caf7-4074-a982-3924283b2972.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-1837-10A (Blood Derived Normal), aliquot TCGA-27-1837-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6bfa06b-e42f-4c1e-9e07-2b3a7f28905e

The open-access MAF lists 65 somatic variants for this specimen: 49 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 15, Frame Shift Ins 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 29/55 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs398123329, CM109589, CM151668, COSV64291992, COSV64300125; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.11049C>A p.S3683R | Missense Mutation (SNP) | VAF 173/457 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71284479; called by muse, mutect2, varscan2
- ABCA5 | c.1454A>C p.K485T | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67016024; called by muse, mutect2, varscan2
- ADAMTS15 | c.2732G>A p.R911Q | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as rs748790827, COSV54503801; called by muse, mutect2, varscan2
- CCDC12 | c.286G>A p.E96K (on ENST00000425441 / NM_001277074.1; = p.E109K on NM_144716.5) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.387); catalogued as rs566710688, COSV52765163; called by muse, mutect2, varscan2
- COL26A1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs772822189, COSV58121667, COSV58128628; called by muse, mutect2, varscan2
- CYP4X1 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 109/227 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.668); catalogued as rs753837465, COSV64149903; called by muse, mutect2, varscan2
- DPYSL5 | c.617T>C p.L206P | Missense Mutation (SNP) | VAF 149/437 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV56509653; called by muse, mutect2, varscan2
- ENPEP | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 107/305 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs1489093019, COSV54447993; called by muse, mutect2, varscan2
- FBXL13 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.09); catalogued as rs180901632, COSV57535706; called by muse, mutect2, varscan2
- FDPS | c.635A>G p.Y212C | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs1432292015, COSV63113988; called by muse, mutect2, varscan2
- GLTP | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 124/332 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.166); catalogued as COSV59172528; called by muse, mutect2, varscan2
- GRIP2 | c.1298G>A p.R433Q (on ENST00000619221; = p.R336Q on NM_001080423.4) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs781920501; called by muse, mutect2
- INIP | c.143G>T p.R48I | Missense Mutation (SNP) | VAF 67/363 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV65295258; called by muse, mutect2, varscan2
- MRPL24 | c.52dup p.H18Pfs*34 | Frame Shift Ins (INS) | VAF 15/136 reads (11%) | catalogued as rs760797871; called by mutect2, varscan2
- NCOR1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 79/261 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV51964795; called by muse, mutect2, varscan2
- NRXN3 | c.593C>A p.A198D | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.031); catalogued as COSV73587194; called by muse, mutect2, varscan2
- OR4D5 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 274/561 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs746149575, COSV58306026; called by muse, mutect2, varscan2
- PARD3B | c.809C>A p.A270D | Missense Mutation (SNP) | VAF 39/388 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62504427; called by muse, mutect2
- PCDHGA11 | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 23/340 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53912590; called by muse, mutect2
- PCDHGB2 | c.1025A>C p.D342A | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53912579; called by muse, mutect2, varscan2
- RELN | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 90/259 reads (35%) | catalogued as COSV58990404; called by muse, mutect2, varscan2
- RFPL1 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 129/353 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs748957165, COSV62977497; called by muse, mutect2, varscan2
- RGL2 | c.608dup p.S204Qfs*3 | Frame Shift Ins (INS) | VAF 29/157 reads (18%) | catalogued as rs762949421; called by mutect2, varscan2
- SETDB1 | c.3766C>T p.R1256W (on ENST00000271640 / NM_001366417.1; = p.R1255W on NM_012432.4) | Missense Mutation (SNP) | VAF 66/133 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1395729846, COSV54976407; called by muse, mutect2, varscan2
- SLC4A1 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.087); catalogued as rs201280873; called by muse, mutect2, varscan2
- SLC9C1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs749177716, COSV59886093; called by muse, mutect2, varscan2
- TAPT1 | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs765524755; called by mutect2, varscan2
- TMTC2 | c.1876C>T p.L626F | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as rs1252764702; called by mutect2, varscan2
- TPR | c.3812T>C p.V1271A | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.056); catalogued as COSV66599962; called by muse, mutect2, varscan2
- TUBA1A | c.1235G>A p.G412E | Missense Mutation (SNP) | VAF 152/365 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as COSV55496989, COSV55498595; called by muse, mutect2, varscan2
- UGT2B28 | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 112/568 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59431034; called by muse, mutect2, varscan2
- WDSUB1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100701874; called by muse, mutect2
- ZNF48 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141362652; called by muse, mutect2, varscan2
- ARMC1 | c.812C>A p.T271K | Missense Mutation (SNP) | VAF 15/326 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2
- BTN1A1 | c.893C>A p.A298D | Missense Mutation (SNP) | VAF 27/666 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2
- CACNA2D4 | c.2103G>T p.Q701H | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNGB1 | c.1842G>T p.K614N | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); called by muse, mutect2
- ELOA2 | c.1595A>G p.Q532R | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ERICH3 | c.251A>G p.H84R | Missense Mutation (SNP) | VAF 18/279 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.363); called by muse, mutect2
- HK2 | c.241C>A p.L81M | Missense Mutation (SNP) | VAF 38/1180 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2
- HSPA12A | c.89A>G p.D30G | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); called by mutect2, varscan2
- KIAA0895 | c.989G>T p.R330M (on ENST00000297063 / NM_001100425.2; = p.R279M on NM_015314.3) | Missense Mutation (SNP) | VAF 28/509 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC52 | c.305A>G p.K102R | Missense Mutation (SNP) | VAF 46/580 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by mutect2, varscan2
- LY6G5B | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 52/690 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.71); called by muse, mutect2
- NEIL2 | c.846C>A p.H282Q | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2
- PTPRC | c.3220C>A p.Q1074K | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2
- TPST1 | c.302C>A p.T101N | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- USP19 | c.970T>A p.F324I | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- CLDN14 | c.600C>T p.A200= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV59772247; called by muse, mutect2, varscan2
- CLSTN3 | c.2175C>T p.L725= | Silent (SNP) | VAF 42/133 reads (32%) | catalogued as rs774966830, COSV56934571; called by muse, mutect2, varscan2
- GRM3 | c.843G>A p.S281= | Silent (SNP) | VAF 61/208 reads (29%) | catalogued as COSV100862169, COSV64468578; called by muse, mutect2, varscan2
- KLHL12 | c.1101C>A p.V367= | Silent (SNP) | VAF 16/242 reads (7%) | called by muse, mutect2
- MYH3 | c.3639G>T p.R1213= | Silent (SNP) | VAF 16/443 reads (4%) | called by muse, mutect2
- NCAM1 | c.1803C>T p.S601= (on ENST00000316851 / NM_181351.5; = p.S591= on NM_000615.7) | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as rs536431053, COSV57516384; called by muse, mutect2, varscan2
- OR5H1 | c.309G>A p.S103= | Silent (SNP) | VAF 133/310 reads (43%) | catalogued as rs779446848, COSV63401624, COSV63401900; called by muse, mutect2, varscan2
- OR8H1 | c.495G>T p.L165= | Silent (SNP) | VAF 11/212 reads (5%) | catalogued as rs775066739, COSV57293666; called by muse, mutect2
- PCDHB15 | c.1659C>T p.D553= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV50858046; called by muse, mutect2, varscan2
- SNX21 | c.559C>A p.R187= | Silent (SNP) | VAF 18/208 reads (9%) | catalogued as COSV54168459; called by muse, mutect2
- SPIN2B | c.366C>T p.A122= | Silent (SNP) | VAF 116/216 reads (54%) | catalogued as COSV52068751; called by muse, mutect2, varscan2
- STRA6 | c.1974C>T p.A658= | Silent (SNP) | VAF 26/222 reads (12%) | catalogued as rs1476447561; called by muse, mutect2, varscan2
- TAMM41 | c.630C>T p.A210= | Silent (SNP) | VAF 28/266 reads (11%) | called by mutect2, varscan2
- XRCC1 | c.1068C>T p.D356= | Silent (SNP) | VAF 24/320 reads (8%) | called by muse, mutect2
- ZKSCAN2 | c.2712A>G p.E904= | Silent (SNP) | VAF 89/217 reads (41%) | catalogued as COSV60155902; called by muse, mutect2, varscan2
- SKA2 | c.33+130C>T | Intron (SNP) | VAF 57/185 reads (31%) | catalogued as rs755480328, COSV99231307; called by muse, mutect2, varscan2
